Gene-level copy-number profile of tumor specimen TCGA-69-7761-01A from TCGA case TCGA-69-7761, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 85.0 years (31,041 days).
Specimen TCGA-69-7761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.514c8afe-35ee-4017-bc7c-0e2229c7d4ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-7761-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e299d11d-170e-4bea-bc77-f76417228d73

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 2: 8,087; copy number 3: 12,645; copy number 4: 34,352; copy number 5: 4,227; copy number 6: 17; copy number 7: 10; copy number 9: 210; copy number 10: 139; copy number 14: 4; copy number 16: 47; copy number 27: 4; copy number 31: 3; copy number 105: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-7761-01A-11D-2166-01): tumor purity 0.23, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,685,439–13,279,692, 9 genes (within-gene range 0–2): TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ.
- chr9:16,203,935–17,503,923, 13 genes: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr9:21,278,050–23,438,700, 42 genes (within-gene range 0–2): IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 418 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,375,580–155,745,071, 1 gene, copy number 16 (within-gene range 3–16): PLCH1.
- chr3:155,401,329–157,533,619, 46 genes, copy number 16 (within-gene range 7–16): AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2, RPL6P7, AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1, AC104472.4, GMPS, AC104472.5, SETP14, VN2R1P, KCNAB1, ALG1L15P, MRE11P1, AC091607.2, AC091607.1, KCNAB1-AS2, KCNAB1-AS1, AC084036.1, SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4, LEKR1, KLF3P2, AC117392.1, RN7SKP177, LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146, AC092944.1, AC092944.2, AC092944.3, VEPH1.
- chr3:159,711,852–163,232,149, 42 genes, copy number 9–14 (within-gene range 3–14): AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1.
- chr3:163,115,429–163,116,186, 1 gene, copy number 14: RPS6P4.
- chr3:167,239,843–173,336,965, 108 genes, copy number 10 (broad region; genes not listed).
- chr3:182,365,147–183,684,519, 31 genes, copy number 10: AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24.
- chr3:193,398,967–198,222,513, 171 genes, copy number 9 (broad region; genes not listed).
- chr17:30,316,333–30,360,566, 3 genes, copy number 31: TMIGD1, Y_RNA, RNU6-990P.
- chr17:39,665,349–39,944,734, 15 genes, copy number 27–105: TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
